TCGA case TCGA-05-4426 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/36bf02f8-c1c8-49f9-a417-adf88a205c70

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 71 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma with mixed subtypes (the primary disease): ICD-O-3 morphology code: 8255/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 71.4 years (26,084 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 72.7 years (26,541 days); Days to diagnosis: 457 days (1.3 years); Prior treatment: Yes.

Follow-up (2 entries)
- Day 457 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 791 days (2.2 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 20.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-05-4426-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.9; Shortest dimension: 0.5.
  Slide TCGA-05-4426-01A-01-BS1: Section location: Bottom; Percent tumor cells: 88; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 10.
  Slide TCGA-05-4426-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
- Sample TCGA-05-4426-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-05-4426-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Lower.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 791 days; disease-specific survival: no event (censored), 791 days; disease-free interval: event (new tumor event after initially disease-free), 457 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 457 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-05-4426-01A-01D-1204-01): tumor purity 0.7, ploidy 1.99, whole-genome doublings 0.
